Somatic mutation profile of tumor specimen TARGET-20-PATKKI-09A (aliquot TARGET-20-PATKKI-09A-01D) from TARGET case TARGET-20-PATKKI, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,238 days).
Specimen TARGET-20-PATKKI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb2316ad-b8b0-445e-a64a-d19a478e90e4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATKKI-14A (Bone Marrow Normal), aliquot TARGET-20-PATKKI-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c657cdd4-caa2-4c86-8580-a95d1cb02ec5

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, 3'UTR 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 19/236 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 62/214 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1101_1102dup p.R368Hfs*70 | Frame Shift Ins (INS) | VAF 52/153 reads (34%) | catalogued as COSV60065714, COSV60066671, COSV60067526, COSV60073219, COSV60075996, COSV60077962, COSV60079089, COSV60085405; called by pindel, varscan2
- USP34 | c.6999G>A p.T2333= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as rs1043166354; called by muse, mutect2
- FLNB | c.*762T>C | 3'UTR (SNP) | VAF 17/276 reads (6%) | called by muse, mutect2
- MAPK14 | chr6:36027768 T>G | 5'Flank (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2
